Gene-level copy-number profile of tumor specimen TCGA-B5-A0KB-01B from TCGA case TCGA-B5-A0KB, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 62.1 years (22,669 days).
Specimen TCGA-B5-A0KB-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.2b83f094-c657-4d73-8310-41650f69b0b6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B5-A0KB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f4c8b019-3c99-477b-89e4-615d41f77cb6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 73; copy number 1: 23,383; copy number 2: 34,026; copy number 3: 1,183; copy number 4: 1,076; copy number 6: 75.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-B5-A0KB-01): tumor purity 0.38, ploidy 3.61, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 70 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:86,935,540–89,139,458, 70 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 75 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:113,157,325–113,563,298, 12 genes, copy number 6: PSD4, AC016683.1, PAX8-AS1, PAX8, AC016745.1, IGKV1OR2-108, AC016745.2, CBWD2, FOXD4L1, LINC01961, PGM5P4-AS1, PGM5P4.
- chr3:169,709,295–170,454,733, 31 genes, copy number 6: SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11.
- chr3:170,423,103–170,423,162, 1 gene, copy number 6: MIR6828.
- chr3:172,039,578–173,336,965, 21 genes, copy number 6 (within-gene range 4–6): FNDC3B, RPS27AP8, RN7SL141P, AC092964.1, BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1, SPATA16, AC068759.1.
- chr3:173,644,231–173,644,711, 1 gene, copy number 6: AC092967.1.
- chr3:175,675,087–176,114,537, 9 genes, copy number 6: AC119744.1, UBE2V1P2, RNU6-1317P, NAALADL2-AS1, AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1.

Autosomal genes at a single copy (total copy number 1): 20,974. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
